HCMI case HCM-SANG-1329-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/612e9381-a24f-49cb-8d48-1f4e1b90f64c

Demographics
Sex at birth: male; Days to birth: -16,984 days (46.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Cardia, NOS; Classification of tumor: primary; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No; Esophageal columnar dysplasia degree: Negative/ No Dysplasia; Esophageal columnar metaplasia present: Yes; Gastric esophageal junction involvement: Yes; Goblet cells columnar mucosa present: Yes; Uicc clinical stage: Stage IB; Uicc pathologic m: M0; Uicc pathologic n: N0; Uicc pathologic stage: Stage IB; Uicc pathologic t: T1b; Uicc staging system edition: 7th.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (1 entry)
- Days to follow up: 0 days; Barretts esophagus goblet cells present: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.
- Timepoint category: Prior to Diagnosis; Reflux treatment type: Proton Pump Inhibitors; Risk factor treatment: Yes; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Comorbidities: Barrett's Esophagus; Risk factors: Barrett's Esophagus.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol intensity: Heavy Drinker; Alcohol days per week: 7.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (4 samples)
- Sample HCM-SANG-1329-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
- Sample HCM-SANG-1329-C15-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-1329-C15-85A-01D-A80T-32, HCM-SANG-1329-C15-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
